TCGA case TCGA-CS-4942 — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Thomas Jefferson University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/230f5fa7-aa36-41ea-b40b-08f520767bd5

Demographics
Sex at birth: female; Race: black or african american; Country of residence at enrollment: United States; Age at index: 44 years; Vital status: Dead; Days to death: 1,335 days (3.7 years).

Diagnoses (2)
1. Astrocytoma, anaplastic (the primary disease): ICD-O-3 morphology code: 9401/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Nervous system, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 44.6 years (16,297 days); Year of diagnosis: 2006; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; First symptom longest duration: 0-30 Days; First symptom prior to diagnosis: Altered Mental Status; Sites of involvement: Brain, Frontal lobe; Supratentorial localization: White Matter.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 146 days; Days to treatment end: 187 days; Treatment dose: 50 cGy; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation, Radioisotope; Initial disease status: Recurrent Disease; Days to treatment start: 1,205 days (3.3 years); Days to treatment end: 1,205 days (3.3 years); Treatment dose: 30 cGy; Course number: 2; Number of fractions: 10; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 1,241 days (3.4 years); Days to treatment end: 1,260 days (3.4 years); Number of cycles: 6; Treatment dose: 4,800 mg; Prescribed dose: 800; Prescribed dose units: mg; Route of administration: Intravenous.
   Recorded as not given: Antiseizure Treatment, preoperative; Radiation Therapy, NOS to Head, Face or Neck, NOS, prior to diagnosis; Steroid Therapy, preoperative.
2. Recurrence of diagnosis 1 (Astrocytoma, anaplastic). Age at diagnosis: 47.9 years (17,481 days); Days to diagnosis: 1,184 days (3.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 1,189 days (3.3 years); Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Surgery, NOS to Distant Site.

Follow-up (4 entries)
- Day -21 (preoperative): Karnofsky performance status: 90; ECOG performance status: 1.
- Day 1,184 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 1,184 days (3.2 years).
- Day 1,226 (preoperative): Karnofsky performance status: 70; ECOG performance status: 2.
- Days to follow up: 1,335 days (3.7 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Altered Mental Status / Motor / Movement Change / Seizure / Sensory Changes.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CS-4942-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.5; Intermediate dimension: 0.4; Shortest dimension: 0.4.
  Slide TCGA-CS-4942-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-CS-4942-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-CS-4942-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CS-4942-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Astrocytoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; History ionizing radiation to head: No; Tumor status: With tumor; Tumor site: Supratentorial, Frontal Lobe; History seizures: Yes; History headaches: No; Symp changes mental status: Yes; Symp changes visual: No; Symp changes sensory: Yes; Symp changes motor movement: Yes; Related symptom first present: Mental Status Changes; First symptom longest duration: 0 - 30 Days; History asthma: No; History eczema: No; Histor hay fever: No; History dust mold allergy: No; Allergy food diagnosis indicator: No; Allergy animals insects diagnosis indicator: No; History neoadjuvant steroid treatment: No; History neoadjuvant medication: No; Family history brain tumor: No; Idh1 mutation test indicator: No; Inherited genetic syndrome indicator: No.
- Drug treatment: Pharmaceutical therapy drug name: Avastin; Therapy regimen: Progression.
- Drug treatment, Route of administrations: Route of administration: IV.
- Follow-up form: New tumor event surgery: Yes; Tumor status: With tumor; New tumor event pharmaceutical treatment: Yes; New tumor event radiation treatment: Yes; New tumor event surgery met: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,335 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,335 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,184 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CS-4942-01A-01D-1466-01): tumor purity 0.77, ploidy 2.05, whole-genome doublings 0.
